Gene-level copy-number profile of tumor specimen TCGA-94-8490-01A from TCGA case TCGA-94-8490, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 70.1 years (25,588 days).
Specimen TCGA-94-8490-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d418abe2-b53b-4f20-9891-85f3b38c3b6a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-94-8490-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b8d214d7-45ac-4b5a-82ed-dd7872334a4c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 88; copy number 1: 15,065; copy number 2: 37,266; copy number 3: 3,786; copy number 4: 3,166; copy number 5: 439; copy number 6: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-94-8490-01A-11D-2322-01): tumor purity 0.79, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 87 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,410,969–29,636,853, 87 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 441 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:143,265,222–148,591,927, 48 genes, copy number 5 (within-gene range 4–5): SLC9A9, AC131210.1, SLC9A9-AS1, SLC9A9-AS2, GAPDHP47, ST13P15, AC073358.1, AC107421.1, DIPK2A, RNA5SP144, AC011592.1, LARP7P4, GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4, AC130509.1, AC069528.1, PLSCR2, AC069528.2, PLSCR1, RNU6-428P, PLSCR5, PLSCR5-AS1, AC092957.1, LINC02010, RNU6-505P, RPL21P71, ZIC4, ZIC4-AS1, ZIC1, NPM1P28, AC092925.1, AC092958.1, AC092958.4, LINC02032, AC092958.3, AC092958.2, AC025566.1, HNRNPA1P20, LINC02045, LINC02046, AC069410.1.
- chr3:163,026,396–167,066,320, 30 genes, copy number 5: AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P, AC084017.1, MIR1263, LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74.
- chr3:172,889,357–176,114,537, 26 genes, copy number 5–6: SPATA16, AC068759.1, NLGN1, AC092967.1, NLGN1-AS1, RN7SKP234, ANAPC15P2, AC069218.1, NAALADL2, RN7SKP40, EEF1B2P8, NAALADL2-AS3, NAALADL2-AS2, MIR4789, RNU6-1233P, AC008180.3, RNU4-91P, AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1, AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1.
- chr3:176,515,103–176,515,151, 1 gene, copy number 5: MIR7977.
- chr3:187,217,282–192,767,764, 62 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr9:35,147,410–37,358,149, 78 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:187,853–6,780,246, 196 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,688. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
